TCGA case TCGA-CG-5733 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8a9afa5e-63ce-41eb-aafb-b0b03653da5a

Demographics
Sex at birth: female; Country of residence at enrollment: Germany; Age at index: 83 years; Vital status: Dead; Days to death: 641 days (1.8 years).

Diagnoses (2)
1. Adenocarcinoma, intestinal type (the primary disease): ICD-O-3 morphology code: 8144/3; ICD-10 code: C16.3; Tissue or organ of origin: Gastric antrum; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 83.9 years (30,650 days); Year of diagnosis: 2003; AJCC staging edition: 5th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 641 days (1.8 years).
   Pathology details: Lymph nodes positive: 7; Lymph nodes tested: 32.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Age at diagnosis: 85.1 years (31,077 days); Days to diagnosis: 427 days (1.2 years); Prior treatment: Yes.

Follow-up (2 entries)
- Day 427 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 641 days (1.8 years); Disease response: With Tumor.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CG-5733-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.3.
  Slide TCGA-CG-5733-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
  Slide TCGA-CG-5733-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
- Sample TCGA-CG-5733-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CG-5733-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.8; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Intestinal Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Anatomic organ subdivision: Antrum/Distal; Lymph nodes examined: Yes; Cancer procurement city: Hamburg; History reflux disease indicator: No; History barretts esophageal indicator: No; Number of relatives with stomach cancer: 0.
- Follow-up form: Lost to follow-up: No; New tumor event diagnosis indicator: Yes; Tumor status: With tumor; Treatment outcome first course: Progressive Disease; Treatment outcome at TCGA followup: Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 641 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 641 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 427 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CG-5733-01A-11D-1599-01): tumor purity 0.6, ploidy 2.1, whole-genome doublings 0.
